Somatic mutation profile of tumor specimen TCGA-3G-AB0O-01A (aliquot TCGA-3G-AB0O-01A-22D-A423-09) from TCGA case TCGA-3G-AB0O, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type B1, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 48.0 years (17,528 days).
Specimen TCGA-3G-AB0O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a8f18d8-f016-4e88-bd7c-5780853aa468.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3G-AB0O-11A (Solid Tissue Normal), aliquot TCGA-3G-AB0O-11A-31D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c50e5d31-836f-4946-a984-e3bdfc5613a7

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAST4 | c.2442G>T p.Q814H (on ENST00000403625 / NM_001164664.2; = p.Q625H on NM_015183.3) | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55136450; called by muse, mutect2
